Somatic mutation profile of tumor specimen TCGA-QH-A86X-01A (aliquot TCGA-QH-A86X-01A-11D-A36O-08) from TCGA case TCGA-QH-A86X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 33.9 years (12,385 days).
Specimen TCGA-QH-A86X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cb575cc-4f61-46ef-b6e8-690ede1bccbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A86X-10A (Blood Derived Normal), aliquot TCGA-QH-A86X-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52e73f66-1059-4296-91f3-679b79d934df

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Splice Site 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.452+1G>A p.X151_splice | Splice Site (SNP) | VAF 11/20 reads (55%) | hotspot (GDC flag); catalogued as COSV50552879, COSV50704605; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACSM2B | c.1200C>G p.N400K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV100312339; called by muse, mutect2, varscan2
- DHX29 | c.2020A>G p.R674G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1056529822, COSV99286989; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- IRAK2 | c.742G>T p.G248* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99843695; called by muse, mutect2, varscan2
- LCE2B | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100909281; called by muse, mutect2
- PHLPP2 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100673512; called by muse, mutect2
- POLK | c.1539A>G p.I513M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV54036097, COSV99605555; called by muse, mutect2, varscan2
- PRDM8 | c.396A>T p.K132N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100324935; called by muse, mutect2, varscan2
- SI | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs367672931; called by muse, mutect2, varscan2
- UBR3 | c.5488C>T p.R1830C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1203412476, COSV99773268; called by muse, mutect2, varscan2
- WDR90 | c.1556+1G>A p.X519_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99552755; called by muse, mutect2, varscan2
- ZNF407 | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV99994945; called by muse, mutect2
- IGHV3-48 | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- APOB | c.2721C>T p.H907= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs72653068, COSV99263243; called by muse, mutect2, varscan2
- LMNA | c.1152G>A p.E384= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100738520; called by muse, mutect2, varscan2
- PKP1 | c.1494G>A p.E498= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99824910; called by muse, mutect2, varscan2
- XPA | c.18G>A p.G6= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs761764197, COSV100910288; called by muse, mutect2, varscan2
